Gene-level copy-number profile of tumor specimen TCGA-12-0772-01A from TCGA case TCGA-12-0772, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 46.6 years (17,019 days).
Specimen TCGA-12-0772-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.f04eea08-41a1-4118-9c1e-0ce24da120ae.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-12-0772-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/77073f9b-6dc8-40d6-9088-a58c274614ec

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 6,731; copy number 3: 6,376; copy number 4: 41,001; copy number 5: 445; copy number 6: 4,975; copy number 7: 168; copy number 13: 51; copy number 14: 7; copy number 15: 12; copy number 25: 11; copy number 40: 19; copy number 56: 8; copy number 71: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-12-0772-01A-01D-0333-01): tumor purity 0.75, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 124 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:19,323,428–19,839,080, 1 gene, copy number 14 (within-gene range 5–14): LNC-LBCS.
- chr6:19,438,283–21,602,383, 29 genes, copy number 14–25: RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3.
- chr6:23,854,139–25,732,827, 51 genes, copy number 13: AL139093.1, SPTLC1P2, AL032822.1, HNRNPA1P58, NRSN1, FO393410.1, DCDC2, KAAG1, RNU6-391P, MRS2, GPLD1, ALDH5A1, KIAA0319, KRT8P43, TDP2, ACOT13, AL031775.1, C6orf62, AL031775.2, LINC02828, AL133264.1, GMNN, ARMH2, AL512428.1, RIPOR2, MTCO2P33, PPIAP29, AL160400.1, ASS1P1, RN7SL334P, AL133268.3, AL133268.2, CMAHP, AL133268.4, AL133268.1, AL590084.3, AL590084.1, AL590084.2, KATNBL1P5, AL024509.2, AL024509.1, CARMIL1, Y_RNA, RNU6-987P, AL022170.1, SCGN, PRELID1P2, H2AC1, H2BC1, H2BC2P, H2AC2P.
- chr12:67,424,272–68,971,570, 43 genes, copy number 40–71: NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
